Gene-level copy-number profile of tumor specimen BLGSP-71-21-00187-01A from CGCI case BLGSP-71-21-00187, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 59.9 years (21,862 days).
Specimen BLGSP-71-21-00187-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 09e810da-692c-4615-888f-d05289515576.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-21-00187-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/8b3e9639-994b-4b86-9aaf-d7ec004eb642

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,886; copy number 1: 6,253; copy number 2: 33,778; copy number 3: 8,953; copy number 4: 405; copy number 5: 3,117; copy number 6: 617; copy number 7: 2,831; copy number 8: 33; copy number 9: 29; copy number 10: 11.

Homozygous deletions (total copy number 0; autosomes only): 542 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:124,680,722–124,680,916, 1 gene (within-gene range 0–2): MTND5P22.
- chr6:38,715,311–39,229,475, 11 genes (within-gene range 0–1): DNAH8, RN7SL465P, AL035555.2, AL035555.1, DNAH8-AS1, AL034345.1, AL035690.1, GLP1R, SAYSD1, ANKRD18EP, KCNK5.
- chr9:60,914,407–61,582,675, 13 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3.
- chr9:61,642,383–61,662,690, 2 genes: Y_RNA, AL935212.1.
- chr12:1,970,786–6,270,425, 95 genes (within-gene range 0–1) (broad region; genes not listed).
- chr12:34,162,477–34,249,958, 6 genes: AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr12:113,298,759–130,266,725, 414 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,638 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–207,879,115, 1,684 genes, copy number 5–9 (broad region; genes not listed).
- chr1:210,676,823–248,937,043, 797 genes, copy number 5–6 (broad region; genes not listed).
- chr2:89,252,211–89,600,680, 11 genes, copy number 10: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr7:62,275,361–79,544,853, 417 genes, copy number 5–9 (broad region; genes not listed).
- chr7:79,768,028–80,226,181, 1 gene, copy number 8 (within-gene range 4–8): GNAI1.
- chr7:80,096,600–80,312,456, 3 genes, copy number 8: RPL10P11, RN7SL869P, AC003988.1.
- chr7:80,742,538–98,479,225, 223 genes, copy number 7–8 (broad region; genes not listed).
- chr7:98,846,488–159,233,377, 1,245 genes, copy number 5–7 (broad region; genes not listed).
- chr8:64,091–10,055,041, 222 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:10,474,565–24,359,014, 300 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:24,440,930–24,526,970, 2 genes, copy number 5 (within-gene range 4–5): ADAM7, AC024958.1.
- chr8:27,010,486–43,674,591, 346 genes, copy number 5–7 (broad region; genes not listed).
- chr8:46,549,089–126,329,538, 1,154 genes, copy number 5–7 (broad region; genes not listed).
- chr8:139,727,725–145,066,685, 202 genes, copy number 5–6 (broad region; genes not listed).
- chr10:94,646,364–95,173,187, 15 genes, copy number 5: CTBP2P2, CYP2C18, AL583836.1, CYP2C19, MTND4P19, CYP2C58P, RPL7AP52, CYP2C9, MTND4P20, CYP2C59P, CYP2C60P, AL359672.1, CYP2C8, AL157834.4, AL157834.3.
- chr11:48,245,056–48,580,336, 16 genes, copy number 5: OR4X2, OR4X1, OR4S1, OR4C3, OR4C4P, OR4C5, OR4C2P, OR4C10P, OR4C9P, OR4R1P, OR4A47, OR4A48P, OR4A46P, OR4A40P, OR4A43P, OR4A45P.

Autosomal genes at a single copy (total copy number 1): 6,253. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
